Somatic mutation profile of tumor specimen 0DUEUD from CCDI case PBCLET, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.2 years (4,835 days).
Specimen 0DUEUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fa30854-3048-4ff1-a3fc-6bc0f7f539b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8603b15e-83ff-4a3e-9d7b-9cf3ce769eb6

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NWD2 | c.4697T>C p.I1566T | Missense Mutation (SNP) | VAF 38/616 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1196897422; called by muse, mutect2
- PARS2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758342465, COSV100988345; called by muse, mutect2
- PHF24 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 55/823 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs775490664; called by muse, mutect2
- PIK3CG | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 44/624 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs200175951, COSV63245400; called by muse, mutect2
- SND1 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 76/948 reads (8%) | catalogued as COSV61247711; called by muse, mutect2
- GRM2 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 44/850 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.281); called by muse, mutect2
- NF2 | c.1591A>T p.K531* | Nonsense Mutation (SNP) | VAF 154/321 reads (48%) | called by muse, mutect2, varscan2
- RYR2 | c.13113G>T p.E4371D | Missense Mutation (SNP) | VAF 18/462 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.098); called by muse, mutect2
- ANKRD65 | c.684G>A p.R228= | Silent (SNP) | VAF 40/1036 reads (4%) | called by muse, mutect2
